Somatic mutation profile of tumor specimen RC-B60S-TTP1-A (aliquot RC-B60S-TTP1-A-1-1-D-A93N-47) from RC case RC-B60S, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Angioimmunoblastic T-cell lymphoma; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 55.3 years (20,204 days).
Specimen RC-B60S-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fb3461a-01f9-4ddb-8f64-78c79614f80c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B60S-NM1-A (Bone Marrow Components NOS; tissue type Normal), aliquot RC-B60S-NM1-A-2-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89798469-4613-40a5-9185-57fac6d4d271

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLMN | c.2080T>C p.C694R | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs745714222, COSV54187254; called by muse, mutect2
- CLVS1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs202238473, COSV57981325; called by muse, mutect2, varscan2
- PEG3 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs771139564, COSV55628095; called by muse, mutect2
- SULF2 | c.1862T>C p.L621P | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); catalogued as COSV63420041; called by muse, mutect2
- FAT3 | c.9358A>T p.I3120F | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PRMT1 | c.152A>T p.D51V | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- SBSPON | c.503A>C p.Y168S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SLC4A4 | c.1451C>T p.A484V (on ENST00000264485 / NM_001098484.3; = p.A440V on NM_003759.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.63); PolyPhen probably damaging (1); called by mutect2, varscan2
- TET2 | c.5108dup p.D1704Rfs*9 | Frame Shift Ins (INS) | VAF 7/64 reads (11%) | called by mutect2, varscan2
- ZNF407 | c.4808C>G p.A1603G | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD34B | c.261T>G p.A87= | Silent (SNP) | VAF 40/168 reads (24%) | called by mutect2, varscan2
- DDX39A | c.531G>A p.A177= | Silent (SNP) | VAF 31/222 reads (14%) | catalogued as rs775009962, COSV54391042; called by muse, mutect2, varscan2
- HKDC1 | c.633G>A p.V211= | Silent (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- ITPR1 | c.2340G>A p.A780= (on ENST00000354582; = p.A765= on NM_002222.7) | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as rs748274420, COSV100229494; called by muse, mutect2, varscan2
- MUC5AC | c.5883T>C p.I1961= | Silent (SNP) | VAF 22/238 reads (9%) | catalogued as rs1461033952; called by muse, mutect2
- CTBP2 | c.59-2151T>G | Intron (SNP) | VAF 42/307 reads (14%) | called by muse, mutect2, varscan2
